Somatic mutation profile of tumor specimen TCGA-06-0237-01A (aliquot TCGA-06-0237-01A-02D-1491-08) from TCGA case TCGA-06-0237, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.9 years (27,735 days).
Specimen TCGA-06-0237-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a56a437-6b79-4ae8-a5c2-a8eaf8fb6df2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0237-10A (Blood Derived Normal), aliquot TCGA-06-0237-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e42ccfda-6013-4890-ad94-5c838fb8d211

The open-access MAF lists 41 somatic variants for this specimen: 28 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 24, Silent 13, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 1063/1260 reads (84%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV51765770; called by muse, mutect2, varscan2
- HSD17B4 | c.296-1G>C p.X99_splice (on ENST00000414835 / NM_001199291.3; = p.X74_splice on NM_000414.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 67/141 reads (48%) | catalogued as rs1554062168, COSV56333166; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs199474686, CM010073, COSV55025879; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 43/99 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- USH2A | c.11156G>A p.R3719H | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs527236139, CM148283, COSV56321550; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- XYLT2 | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1423415130, COSV50016614; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRG5 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as rs546977099, COSV61083689; called by muse, mutect2
- CRYGS | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57192020; called by muse, mutect2, varscan2
- CYP2B6 | c.850A>T p.S284C | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.68); catalogued as COSV57842277; called by muse, mutect2, varscan2
- CYP4F2 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs770633305, COSV55616064; called by muse, mutect2, varscan2
- DNAH11 | c.2732T>C p.I911T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV60961222; called by muse, mutect2, varscan2
- DNAH8 | c.9678C>A p.F3226L | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV59421513; called by muse, mutect2, varscan2
- GALE | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV52526362; called by muse, mutect2
- HPSE | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs138550346; called by muse, mutect2, varscan2
- KCNJ5 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 111/223 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201816501, COSV57962723, COSV57965332; called by muse, mutect2, varscan2
- KDM7A | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs756878349, COSV50089983; called by muse, mutect2, varscan2
- KIF4B | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs199820075, COSV101469192, COSV70526998; called by muse, mutect2, varscan2
- NBEA | c.7522G>A p.G2508R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59756880; called by muse, mutect2, varscan2
- NOL11 | c.1277del p.T426Nfs*12 | Frame Shift Del (DEL) | VAF 103/275 reads (37%) | catalogued as COSV53521666; called by mutect2, pindel, varscan2
- OBSCN | c.12014C>T p.A4005V | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.792); catalogued as rs751925970, COSV52785380; called by muse, mutect2, varscan2
- PCDHAC1 | c.1355T>C p.L452P | Missense Mutation (SNP) | VAF 101/202 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV53835854; called by muse, mutect2, varscan2
- PLS1 | c.911T>G p.L304R | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61832530; called by muse, mutect2, varscan2
- RYR2 | c.7570G>A p.V2524I | Missense Mutation (SNP) | VAF 94/291 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.266); catalogued as rs934248102, COSV63687294; called by muse, mutect2, varscan2
- SALL3 | c.1984T>G p.S662A | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV73305715; called by muse, mutect2, varscan2
- SLC17A9 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 260/662 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as rs772910639, COSV64846708; called by muse, mutect2, varscan2
- SLC9C1 | c.29dup p.S11Qfs*3 | Frame Shift Ins (INS) | VAF 24/62 reads (39%) | catalogued as rs749004401; called by mutect2, varscan2
- YJU2 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as COSV53606649; called by muse, mutect2
- QKI | c.934+3_934+6del p.X312_splice | Splice Site (DEL) | VAF 70/184 reads (38%) | called by mutect2, pindel, varscan2
- AGRN | c.1638C>T p.C546= | Silent (SNP) | VAF 70/163 reads (43%) | catalogued as rs142440782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASB5 | c.900T>C p.C300= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV56668241; called by muse, mutect2, varscan2
- CCDC158 | c.2883G>A p.S961= | Silent (SNP) | VAF 99/254 reads (39%) | catalogued as rs376345467; called by muse, mutect2, varscan2
- EEF1A2 | c.783G>A p.T261= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as rs370695849, COSV53204539; ClinVar: likely benign; called by muse, mutect2, varscan2
- FANCD2 | c.813G>A p.S271= | Silent (SNP) | VAF 126/300 reads (42%) | catalogued as rs773072936, CD072417, COSV55031830, COSV55032057; ClinVar: likely benign; called by muse, mutect2, varscan2
- FFAR3 | c.750C>T p.I250= | Silent (SNP) | VAF 120/603 reads (20%) | catalogued as COSV59908633; called by muse, mutect2
- GIPC3 | c.480C>T p.I160= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as COSV59258124, COSV59258804; called by muse, mutect2, varscan2
- IL31RA | c.1470C>A p.I490= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as COSV51678680; called by muse, mutect2
- LIG3 | c.1755C>T p.F585= | Silent (SNP) | VAF 98/255 reads (38%) | catalogued as COSV52005450; called by muse, mutect2, varscan2
- NPTX2 | c.894G>A p.A298= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as rs145736632, COSV55719347; called by muse, mutect2, varscan2
- RIPPLY3 | c.114G>A p.P38= | Silent (SNP) | VAF 59/122 reads (48%) | catalogued as rs781340522, COSV61566447; called by muse, mutect2, varscan2
- TGIF2LX | c.102G>A p.S34= | Silent (SNP) | VAF 59/142 reads (42%) | catalogued as rs200638786, COSV52213058; called by muse, mutect2, varscan2
- YPEL3 | c.177C>T p.C59= (on ENST00000398838 / NM_001145524.2; = p.C97= on NM_031477.5) | Silent (SNP) | VAF 61/106 reads (58%) | catalogued as rs1470658970, COSV54220632; called by muse, mutect2, varscan2
